Somatic mutation profile of tumor specimen ALCH-AEKY-TTP1-A (aliquot ALCH-AEKY-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEKY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.7 years (22,173 days).
Specimen ALCH-AEKY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a928c81-825d-4557-a627-2d1d511f42d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEKY-NB1-A (Blood Derived Normal), aliquot ALCH-AEKY-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4c89986-adce-493e-9ec6-7427416a946d

The open-access MAF lists 347 somatic variants for this specimen: 236 protein-altering or splice-affecting, 73 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 202, Silent 73, Intron 19, Nonsense Mutation 14, Splice Site 8, 3'UTR 7, RNA 6, Frame Shift Del 5, 5'UTR 4, Frame Shift Ins 3, Splice Region 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.635-1G>A p.X212_splice | Splice Site (SNP) | VAF 30/167 reads (18%) | hotspot (GDC flag); catalogued as rs876661024, CS090867, CS993675, COSV64289221, COSV64292432, COSV64296169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.267dup p.S90Lfs*59 | Frame Shift Ins (INS) | VAF 55/153 reads (36%) | catalogued as rs587783062; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ACADM | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 117/438 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763555974; called by muse, varscan2
- ADAMTS7 | c.542A>G p.H181R | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1325732948; called by muse, mutect2, varscan2
- ADCY3 | c.2737-7T>G | Splice Region (SNP) | VAF 28/164 reads (17%) | catalogued as rs764845615; called by muse, mutect2, varscan2
- AIFM1 | c.1105G>T p.V369L | Missense Mutation (SNP) | VAF 108/427 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as rs1444952549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP17 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 114/389 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs546945788; called by muse, mutect2, varscan2
- ARHGAP35 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 51/250 reads (20%) | catalogued as COSV68335666; called by muse, mutect2, varscan2
- ARHGAP35 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.018); catalogued as rs946810282; called by muse, mutect2, varscan2
- ARHGAP35 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs1358966033; called by muse, mutect2, varscan2
- ARHGAP35 | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV68331987; called by muse, mutect2, varscan2
- ARL4C | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV100327071, COSV60214738; called by muse, mutect2, varscan2
- ARMC1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 124/339 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.545); catalogued as rs749931107; called by muse, mutect2, varscan2
- ASTN1 | c.2357C>T p.P786L | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99920095; called by muse, mutect2, varscan2
- ATM | c.3901G>C p.E1301Q | Missense Mutation (SNP) | VAF 37/357 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV53729047, COSV53743796; called by muse, mutect2, varscan2
- ATP1A4 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100927548; called by muse, mutect2, varscan2
- ATRX | c.3124G>T p.G1042* | Nonsense Mutation (SNP) | VAF 51/306 reads (17%) | catalogued as COSV64874141; called by muse, mutect2, varscan2
- BEST2 | c.1211T>A p.M404K | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs759055479, COSV50374801; called by muse, mutect2
- BMPR1A | c.131C>G p.S44* | Nonsense Mutation (SNP) | VAF 81/327 reads (25%) | catalogued as CM014514; called by muse, mutect2, varscan2
- BTBD3 | c.1081C>A p.Q361K | Missense Mutation (SNP) | VAF 74/345 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99656121; called by muse, mutect2, varscan2
- C8A | c.1450C>A p.R484S | Missense Mutation (SNP) | VAF 150/517 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV63483599; called by muse, mutect2, varscan2
- CATSPER3 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 244/582 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs562430942; called by muse, mutect2, varscan2
- CCDC130 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV55582852; called by muse, mutect2
- CCIN | c.1303G>C p.V435L | Missense Mutation (SNP) | VAF 14/233 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.846); catalogued as rs1213305249; called by muse, mutect2
- CDH2 | c.816G>T p.W272C | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52298032; called by muse, mutect2, varscan2
- CDH9 | c.2172C>A p.D724E | Missense Mutation (SNP) | VAF 84/210 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50261778; called by muse, varscan2
- CDK5RAP2 | c.4903C>T p.L1635F | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.694); catalogued as COSV62572977; called by muse, mutect2, varscan2
- CFAP54 | c.5581G>T p.A1861S | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.022); catalogued as COSV61575750; called by muse, mutect2, varscan2
- CHL1 | c.1901C>T p.A634V (on ENST00000397491 / NM_001253387.1; = p.A650V on NM_006614.4) | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs550882168; called by muse, mutect2, varscan2
- CHRD | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV52606659; called by muse, mutect2, varscan2
- CMBL | c.43A>G p.R15G | Missense Mutation (SNP) | VAF 144/340 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs113456062; called by muse, mutect2, varscan2
- CNOT11 | c.160C>G p.P54A | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV56821115; called by muse, mutect2
- CSMD3 | c.4394C>A p.S1465* (on ENST00000297405 / NM_001363185.1; = p.S1361* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 360/811 reads (44%) | catalogued as COSV52350405; called by muse, mutect2, varscan2
- CYP2F1 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs749333476, COSV58526990; called by muse, mutect2, varscan2
- DAPK3 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV56665275; called by muse, mutect2, varscan2
- DKK3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 78/331 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.957); catalogued as COSV58867920, COSV58868183; called by muse, varscan2
- DMPK | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.05); catalogued as COSV99353951; called by muse, mutect2, varscan2
- DNAH3 | c.4601G>T p.G1534V | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768078082; called by muse, mutect2, varscan2
- EFHB | c.1556G>T p.R519L | Missense Mutation (SNP) | VAF 89/338 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV99860202; called by muse, mutect2, varscan2
- EIF3D | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV53401732; called by muse, mutect2, varscan2
- EP300 | c.4355C>T p.P1452L | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV54326768, COSV54346531; called by muse, mutect2
- EPRS1 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748899019; called by muse, mutect2, varscan2
- EXOSC10 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV58666844; called by muse, mutect2
- FADS3 | c.984G>C p.R328S | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs781658214; called by muse, mutect2, varscan2
- GABRR2 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs141718977; called by muse, mutect2, varscan2
- GLRA4 | c.927G>C p.L309F | Missense Mutation (SNP) | VAF 67/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65456991; called by muse, mutect2, varscan2
- GTF2IRD1 | c.207G>C p.K69N | Missense Mutation (SNP) | VAF 61/271 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56085149; called by muse, mutect2, varscan2
- GUCY1A1 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.381); catalogued as COSV99637776; called by muse, mutect2
- HPGD | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 42/410 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1260742171; called by muse, varscan2
- KALRN | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 56/368 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs775004208; called by muse, mutect2, varscan2
- KAT14 | c.1528G>C p.D510H | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100890052; called by muse, mutect2
- KCNQ3 | c.2368C>G p.L790V | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV66481078, COSV66485524; called by muse, mutect2
- KDM4B | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as rs745361851; called by muse, mutect2, varscan2
- KHDC3L | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64863063; called by muse, mutect2
- LAMA3 | c.5701G>C p.E1901Q (on ENST00000313654 / NM_198129.4; = p.E292Q on NM_000227.6) | Missense Mutation (SNP) | VAF 55/651 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as CM050060, COSV52530680; called by muse, mutect2
- LHCGR | c.731C>A p.S244Y | Missense Mutation (SNP) | VAF 94/533 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV54292731, COSV54293079; called by muse, mutect2, varscan2
- LRRIQ4 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs375495668; called by muse, mutect2, varscan2
- LTN1 | c.3002C>T p.S1001L | Missense Mutation (SNP) | VAF 84/261 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs1192485197; called by muse, mutect2, varscan2
- MALSU1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54978078; called by muse, mutect2, varscan2
- MUC4 | c.5524C>G p.P1842A | Missense Mutation (SNP) | VAF 95/1746 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.55); catalogued as COSV62174025; called by muse, mutect2
- MYH7 | c.4762C>A p.R1588S | Missense Mutation (SNP) | VAF 78/284 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs1194197356, COSV62516791; called by muse, mutect2, varscan2
- MYH7B | c.2351T>C p.M784T | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs749490228; called by muse, mutect2, varscan2
- NKX2-6 | c.143C>A p.A48E | Missense Mutation (SNP) | VAF 115/452 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1382359771; called by muse, mutect2, varscan2
- NOA1 | c.1217G>A p.R406K | Missense Mutation (SNP) | VAF 71/325 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV51737843, COSV51738005; called by muse, mutect2, varscan2
- OR4A5 | c.690G>T p.R230S | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs1443925966, COSV60524635; called by muse, mutect2, varscan2
- PCDH11X | c.3392C>A p.T1131N | Missense Mutation (SNP) | VAF 160/589 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV53511304; called by muse, mutect2, varscan2
- PRAMEF27 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 42/722 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1236210771; called by muse, mutect2
- PTPRO | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 101/322 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.236); catalogued as COSV55511296; called by muse, mutect2, varscan2
- RYR2 | c.5044del p.E1682Nfs*25 | Frame Shift Del (DEL) | VAF 62/252 reads (25%) | catalogued as COSV63700005; called by mutect2, pindel, varscan2
- SERPINA4 | c.788G>T p.C263F | Missense Mutation (SNP) | VAF 78/316 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as rs1041285237, COSV100097340; called by muse, mutect2, varscan2
- SHANK1 | c.1105C>G p.R369G | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV53243427; called by muse, mutect2
- SIPA1L3 | c.2579G>T p.R860L | Missense Mutation (SNP) | VAF 68/333 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV55915469, COSV99730070; called by muse, mutect2, varscan2
- SIRPA | c.992G>T p.C331F | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61542207; called by muse, mutect2
- SLC9A9 | c.1631C>G p.S544C | Missense Mutation (SNP) | VAF 105/677 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as COSV57217644; called by muse, mutect2, varscan2
- SLCO1B1 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 122/426 reads (29%) | catalogued as COSV57014444; called by muse, mutect2, varscan2
- SNURF | c.87G>T p.R29S | Missense Mutation (SNP) | VAF 115/363 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.218); catalogued as COSV57596131; called by muse, mutect2, varscan2
- SPCS1 | c.489G>C p.K163N (on ENST00000233025; = p.K96N on NM_014041.5) | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51777565; called by muse, mutect2, varscan2
- SRPX | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.077); catalogued as COSV100655855; called by muse, mutect2, varscan2
- SULF2 | c.641G>C p.R214T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); catalogued as COSV63415556; called by muse, mutect2, varscan2
- SYNE2 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 32/379 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs537840014; called by muse, mutect2
- SYNE2 | c.20176A>T p.I6726F | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as rs886050599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF4B | c.2356del p.A786Lfs*17 | Frame Shift Del (DEL) | VAF 63/300 reads (21%) | catalogued as COSV52312333; called by mutect2, pindel, varscan2
- TCF24 | c.390+1G>A p.X130_splice | Splice Site (SNP) | VAF 18/65 reads (28%) | catalogued as rs1165066070; called by muse, varscan2
- TGM5 | c.1853C>G p.S618C (on ENST00000220420 / NM_201631.4; = p.S536C on NM_004245.4) | Missense Mutation (SNP) | VAF 98/279 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV55012204; called by muse, mutect2, varscan2
- THNSL2 | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1216127117; called by muse, mutect2, varscan2
- TIMD4 | c.575C>G p.T192R | Missense Mutation (SNP) | VAF 307/668 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV50854244; called by muse, mutect2, varscan2
- TM4SF19 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 20/447 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.411); catalogued as COSV56556678; called by muse, mutect2
- TMEM200C | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1206171043; called by muse, mutect2, varscan2
- TMEM238 | c.248T>G p.L83R | Missense Mutation (SNP) | VAF 55/309 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1166167256; called by muse, mutect2, varscan2
- TMIGD3 | c.635C>T p.S212F (on ENST00000369717 / NM_001081976.2; = p.S293F on NM_020683.7) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.47); catalogued as COSV63163311; called by muse, mutect2, varscan2
- TMPRSS11D | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375890965; called by muse, mutect2, varscan2
- TNIK | c.2663C>A p.S888Y | Missense Mutation (SNP) | VAF 31/679 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as COSV52687897, COSV52691923; called by muse, mutect2
- TNN | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99513229; called by muse, mutect2, varscan2
- TNR | c.2805C>A p.S935R | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV54898167, COSV99688832; called by muse, mutect2, varscan2
- TRGV2 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 89/405 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs867129016; called by muse, mutect2, varscan2
- TTN | c.76582G>A p.D25528N (on ENST00000591111; = p.D18104N on NM_003319.4) | Missense Mutation (SNP) | VAF 80/193 reads (41%) | PolyPhen probably damaging (0.998); catalogued as COSV59874279; called by muse, mutect2, varscan2
- UPB1 | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as COSV100387320; called by muse, mutect2, varscan2
- VCL | c.2899C>G p.L967V | Missense Mutation (SNP) | VAF 68/656 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV53011309; called by muse, varscan2
- WASHC3 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.476); catalogued as rs760309752; called by muse, mutect2
- YARS2 | c.1079G>C p.R360P | Missense Mutation (SNP) | VAF 79/439 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV61401508; called by muse, mutect2, varscan2
- YTHDC2 | c.3670C>G p.P1224A | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs935385854, COSV99362824; called by muse, mutect2
- ZNF443 | c.1696G>T p.G566W | Missense Mutation (SNP) | VAF 83/306 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56892710; called by muse, mutect2, varscan2
- ZNF454 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 142/245 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV60768801; called by muse, mutect2, varscan2
- ZNF479 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100482811; called by muse, mutect2, varscan2
- ZXDB | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs773658610; called by muse, mutect2, varscan2
- ABCB8 | c.1891A>G p.T631A (on ENST00000297504 / NM_001282291.2; = p.T614A on NM_007188.5) | Missense Mutation (SNP) | VAF 89/329 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAR | c.585G>T p.W195C | Missense Mutation (SNP) | VAF 95/287 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRF2 | c.1940G>A p.R647K (on ENST00000296862 / NM_001368115.2; = p.R579K on NM_153839.7) | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ADNP2 | c.2671G>T p.E891* | Nonsense Mutation (SNP) | VAF 46/182 reads (25%) | called by muse, mutect2, varscan2
- AFAP1L1 | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AGBL4 | c.1368T>G p.N456K | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AKAP13 | c.4670C>G p.S1557C | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2
- ALDH16A1 | c.1861G>C p.E621Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AMOT | c.3023del p.P1008Rfs*38 (on ENST00000371959 / NM_001113490.1; = p.P599Rfs*38 on NM_133265.3) | Frame Shift Del (DEL) | VAF 91/455 reads (20%) | called by mutect2, pindel, varscan2
- ARHGAP4 | c.2346C>A p.D782E | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- ARHGEF19 | c.1501C>G p.P501A | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ARHGEF19 | c.886C>G p.Q296E | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2
- ARHGEF25 | c.321G>T p.M107I | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASIC1 | c.834G>T p.Q278H | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ASPM | c.6348G>A p.M2116I | Missense Mutation (SNP) | VAF 119/431 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ATPSCKMT | c.695A>T p.Q232L | Missense Mutation (SNP) | VAF 133/281 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ATRX | c.3125G>T p.G1042V | Missense Mutation (SNP) | VAF 47/306 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- B4GALNT4 | c.1038C>A p.Y346* | Nonsense Mutation (SNP) | VAF 73/193 reads (38%) | called by muse, mutect2, varscan2
- BCLAF3 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 86/342 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- BDP1 | c.498G>C p.W166C | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- BICDL1 | c.1107G>A p.W369* | Nonsense Mutation (SNP) | VAF 42/137 reads (31%) | called by muse, mutect2, varscan2
- BIRC6 | c.8671G>T p.A2891S | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BRD3 | c.204G>C p.L68F | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C10orf82 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.193); called by muse, mutect2
- C18orf63 | c.1666G>T p.G556W | Missense Mutation (SNP) | VAF 83/340 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- C2CD3 | c.4805G>T p.C1602F | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- C3orf85 | c.144T>A p.D48E | Missense Mutation (SNP) | VAF 84/525 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CLEC18C | c.440G>T p.C147F | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.003); called by mutect2, varscan2
- COL11A2 | c.4751-1G>A p.X1584_splice (on ENST00000341947 / NM_080680.3; = p.X1477_splice on NM_080679.2) | Splice Site (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- CSMD2 | c.9310G>T p.G3104C | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CTNNA2 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 122/588 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CWH43 | c.1509-2A>T p.X503_splice | Splice Site (SNP) | VAF 22/106 reads (21%) | called by muse, varscan2
- DDR2 | c.403_404insT p.R135Lfs*11 | Frame Shift Ins (INS) | VAF 49/288 reads (17%) | called by mutect2, pindel, varscan2
- DGKD | c.2579A>G p.D860G (on ENST00000264057 / NM_152879.3; = p.D816G on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, varscan2
- DNAH9 | c.3188A>G p.D1063G | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.26); called by muse, mutect2
- DNAH9 | c.3513G>T p.Q1171H | Missense Mutation (SNP) | VAF 14/265 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2
- DSG1 | c.1821+8C>A | Splice Region (SNP) | VAF 159/612 reads (26%) | called by muse, varscan2
- EFHB | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EHBP1 | c.3417-1G>T p.X1139_splice | Splice Site (SNP) | VAF 35/222 reads (16%) | called by muse, mutect2, varscan2
- EHBP1 | c.3417G>T p.L1139= | Splice Region (SNP) | VAF 36/227 reads (16%) | called by muse, mutect2, varscan2
- ELFN1 | c.1817C>A p.A606D | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- EMCN | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.419); called by muse, varscan2
- EPM2AIP1 | c.995G>T p.R332M | Missense Mutation (SNP) | VAF 65/390 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- EVI5L | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 18/162 reads (11%) | called by muse, varscan2
- F5 | c.5464G>A p.E1822K | Missense Mutation (SNP) | VAF 35/704 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.417); called by muse, mutect2
- FAM210B | c.508G>T p.V170F | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.161); called by muse, mutect2
- FOXK2 | c.1646_1669del p.A549_T556del | In Frame Del (DEL) | VAF 70/348 reads (20%) | called by mutect2, varscan2
- FREM2 | c.1475T>G p.L492R | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FTSJ1 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 174/662 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FTSJ1 | c.957G>T p.E319D | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.048); called by mutect2, varscan2
- FUT8 | c.1375C>T p.Q459* (on ENST00000360689 / NM_001371534.1; = p.Q296* on NM_004480.4) | Nonsense Mutation (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- GABRA1 | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 173/319 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GLRX3 | c.277-2_290del p.X93_splice | Splice Site (DEL) | VAF 45/152 reads (30%) | called by mutect2, pindel, varscan2
- GPATCH4 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 50/322 reads (16%) | called by muse, varscan2
- GPKOW | c.1014C>A p.D338E | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GRIK5 | c.2681G>T p.G894V | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- HECW1 | c.4463C>A p.A1488E | Missense Mutation (SNP) | VAF 79/314 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- HELZ2 | c.4261G>T p.G1421C (on ENST00000467148 / NM_001037335.2; = p.G852C on NM_033405.3) | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- HEPH | c.1251C>A p.F417L (on ENST00000343002; = p.F150L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- HMX3 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HOXD13 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 83/173 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- INSR | c.2889C>G p.I963M | Missense Mutation (SNP) | VAF 80/372 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.165); called by muse, varscan2
- INTS13 | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 34/456 reads (7%) | called by muse, mutect2
- ITGA9 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 24/650 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KDM4B | c.1873T>G p.S625A | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- KLRG1 | c.44C>A p.A15E | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2
- LAMC3 | c.4472G>T p.R1491M | Missense Mutation (SNP) | VAF 163/555 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- LRCH2 | c.1763T>C p.M588T | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRP1 | c.3628C>G p.L1210V | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.138); called by muse, mutect2
- LUC7L | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- MAGEB4 | c.1008G>T p.R336S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- MCF2 | c.2614C>T p.Q872* | Nonsense Mutation (SNP) | VAF 38/171 reads (22%) | called by muse, mutect2, varscan2
- MME | c.556A>C p.K186Q | Missense Mutation (SNP) | VAF 57/520 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MRPL19 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MUC22 | c.1321A>G p.T441A | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- NAV3 | c.5846A>G p.K1949R (on ENST00000397909 / NM_001024383.2; = p.K1927R on NM_014903.6) | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); called by muse, varscan2
- NCKAP5 | c.2824A>G p.R942G | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- NDC1 | c.1507A>T p.T503S | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NOC3L | c.825C>G p.I275M | Missense Mutation (SNP) | VAF 120/345 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR52B6 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- OTC | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 125/463 reads (27%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHA10 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 197/389 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB7 | c.2233C>A p.Q745K | Missense Mutation (SNP) | VAF 173/984 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PGP | c.923A>T p.Y308F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2
- PIK3C2B | c.4555C>A p.L1519I | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PKD2 | c.2198G>C p.G733A | Missense Mutation (SNP) | VAF 14/436 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.043); called by muse, mutect2
- PMS2 | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 131/444 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PNMA2 | c.949G>C p.D317H | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- PPM1L | c.465G>C p.E155D | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, varscan2
- PPM1L | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.167); called by muse, varscan2
- PRAMEF15 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 32/726 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PRIM1 | c.368+1G>T p.X123_splice | Splice Site (SNP) | VAF 67/268 reads (25%) | called by muse, mutect2, varscan2
- PRPS1L1 | c.550C>A p.Q184K | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RASGRP2 | c.1663G>T p.V555L | Missense Mutation (SNP) | VAF 103/453 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RBM11 | c.791G>C p.R264T | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); called by muse, varscan2
- RC3H2 | c.3139G>C p.D1047H | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- RLIM | c.1215G>T p.M405I | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- RPS6KA6 | c.1391C>A p.P464H | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RRP12 | c.994A>G p.R332G | Missense Mutation (SNP) | VAF 125/296 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- RYK | c.1452C>G p.I484M (on ENST00000620660 / NM_001005861.2; = p.I481M on NM_002958.4) | Missense Mutation (SNP) | VAF 90/658 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SAV1 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2
- SCML1 | c.301C>G p.H101D (on ENST00000380041 / NM_001037540.3; = p.H74D on NM_006746.6) | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SCN5A | c.2950C>A p.L984I | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- SEL1L2 | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 62/291 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETD7 | c.580G>C p.D194H | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SHC1 | c.1076C>T p.P359L (on ENST00000368445 / NM_183001.5; = p.P249L on NM_003029.5) | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- SLC13A4 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- SLC20A1 | c.942G>C p.E314D | Missense Mutation (SNP) | VAF 63/394 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SLC22A31 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A18 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 113/307 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SLC7A10 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLC9B2 | c.872del p.G291Afs*2 | Frame Shift Del (DEL) | VAF 34/82 reads (41%) | called by mutect2, pindel, varscan2
- SLC9B2 | c.90+1G>T p.X30_splice | Splice Site (SNP) | VAF 98/215 reads (46%) | called by muse, mutect2, varscan2
- SPZ1 | c.687A>T p.K229N | Missense Mutation (SNP) | VAF 119/226 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SRPX | c.486G>T p.M162I | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SYP | c.776C>A p.P259H | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- TAS2R40 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TG | c.4554A>C p.E1518D | Missense Mutation (SNP) | VAF 109/834 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM145 | c.1048C>G p.P350A | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- TMEM161B | c.846del p.L283Sfs*3 | Frame Shift Del (DEL) | VAF 124/321 reads (39%) | called by mutect2, pindel*, varscan2
- TNRC18 | c.4059G>T p.Q1353H | Missense Mutation (SNP) | VAF 88/263 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- TRAPPC10 | c.1585C>T p.Q529* | Nonsense Mutation (SNP) | VAF 26/371 reads (7%) | called by muse, mutect2
- TRMT9B | c.1227G>A p.M409I | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- TSHZ2 | c.1443C>G p.S481R | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- UHRF1BP1 | c.1546T>G p.Y516D | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP24 | c.5658G>A p.M1886I | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.557); called by muse, varscan2
- WDFY3 | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- WNK3 | c.4081T>G p.F1361V | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP36L2 | c.1107dup p.S370Qfs*104 | Frame Shift Ins (INS) | VAF 55/247 reads (22%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.647A>T p.H216L | Missense Mutation (SNP) | VAF 187/538 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF184 | c.1044C>G p.H348Q | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- A2M | c.1176C>T p.N392= | Silent (SNP) | VAF 59/390 reads (15%) | catalogued as COSV59391371; called by muse, mutect2, varscan2
- A4GNT | c.237T>A p.P79= | Silent (SNP) | VAF 153/318 reads (48%) | called by muse, mutect2, varscan2
- ABCA7 | c.378G>A p.G126= | Silent (SNP) | VAF 58/194 reads (30%) | called by muse, mutect2, varscan2
- ACSM2A | c.1338C>T p.D446= (on ENST00000219054; = p.D367= on NM_001308169.2) | Silent (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- ACSM2B | c.1338C>T p.D446= | Silent (SNP) | VAF 36/429 reads (8%) | called by muse, mutect2
- ACTA2 | c.696C>T p.A232= | Silent (SNP) | VAF 84/340 reads (25%) | catalogued as rs749557185, COSV56517563; called by muse, mutect2, varscan2
- AMZ1 | c.900G>C p.L300= | Silent (SNP) | VAF 25/484 reads (5%) | called by muse, mutect2
- ANO1 | c.1992C>T p.L664= | Silent (SNP) | VAF 49/198 reads (25%) | catalogued as rs377131457; called by muse, mutect2, varscan2
- APOB | c.6567T>C p.Y2189= | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- BTBD18 | c.1812T>C p.D604= | Silent (SNP) | VAF 50/271 reads (18%) | catalogued as rs1440835824; called by muse, mutect2, varscan2
- CDH9 | c.1957C>A p.R653= | Silent (SNP) | VAF 126/328 reads (38%) | catalogued as COSV50320975, COSV99142080; called by muse, mutect2, varscan2
- CHMP7 | c.1032A>G p.A344= | Silent (SNP) | VAF 54/191 reads (28%) | called by muse, mutect2, varscan2
- CLCN4 | c.1431G>T p.A477= | Silent (SNP) | VAF 54/216 reads (25%) | called by muse, varscan2
- CRB1 | c.4083G>T p.L1361= | Silent (SNP) | VAF 167/617 reads (27%) | called by muse, mutect2, varscan2
- CYP2E1 | c.630C>G p.L210= | Silent (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- DGKZ | c.2436G>A p.Q812= (on ENST00000454345 / NM_001105540.2; = p.Q624= on NM_003646.4) | Silent (SNP) | VAF 22/323 reads (7%) | catalogued as COSV58989705; called by muse, mutect2
- DNHD1 | c.13773C>T p.R4591= | Silent (SNP) | VAF 59/230 reads (26%) | called by muse, mutect2, varscan2
- DUOXA2 | c.336C>G p.L112= | Silent (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
- ECM1 | c.732C>T p.F244= | Silent (SNP) | VAF 26/343 reads (8%) | catalogued as COSV60871647; called by muse, mutect2
- EFCAB6 | c.1239G>A p.L413= | Silent (SNP) | VAF 33/172 reads (19%) | called by muse, mutect2, varscan2
- EHD4 | c.193C>T p.L65= | Silent (SNP) | VAF 64/209 reads (31%) | called by muse, mutect2, varscan2
- EIF4G3 | c.3963T>A p.A1321= | Silent (SNP) | VAF 14/336 reads (4%) | called by muse, mutect2
- ELK1 | c.585G>T p.G195= | Silent (SNP) | VAF 47/190 reads (25%) | called by muse, mutect2, varscan2
- EMD | c.669C>A p.V223= | Silent (SNP) | VAF 30/144 reads (21%) | called by muse, mutect2, varscan2
- ENTPD4 | c.1443T>C p.A481= | Silent (SNP) | VAF 50/240 reads (21%) | catalogued as rs201349673; called by muse, mutect2, varscan2
- EP300 | c.6423G>A p.Q2141= | Silent (SNP) | VAF 32/185 reads (17%) | catalogued as rs1479937842, COSV54331436; called by muse, mutect2, varscan2
- FOLH1 | c.1908A>G p.V636= | Silent (SNP) | VAF 33/118 reads (28%) | called by muse, mutect2, varscan2
- GDF1 | c.111C>G p.A37= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, varscan2
- GFY | c.705T>C p.P235= | Silent (SNP) | VAF 60/234 reads (26%) | called by muse, mutect2, varscan2
- HNRNPC | c.291G>A p.V97= | Silent (SNP) | VAF 16/282 reads (6%) | called by muse, mutect2
- IGKV2D-29 | c.228T>A p.V76= | Silent (SNP) | VAF 91/163 reads (56%) | called by muse, mutect2, varscan2
- IRX2 | c.387C>A p.L129= | Silent (SNP) | VAF 206/518 reads (40%) | catalogued as COSV57412440; called by muse, mutect2, varscan2
- KCNC2 | c.513C>A p.T171= | Silent (SNP) | VAF 83/316 reads (26%) | catalogued as COSV54377019; called by muse, mutect2, varscan2
- KCNQ2 | c.1620C>T p.I540= (on ENST00000359125 / NM_172107.4; = p.I512= on NM_004518.6) | Silent (SNP) | VAF 77/318 reads (24%) | called by muse, mutect2, varscan2
- LAMA2 | c.441C>A p.P147= | Silent (SNP) | VAF 110/252 reads (44%) | called by muse, mutect2, varscan2
- LEUTX | c.234T>C p.S78= | Silent (SNP) | VAF 119/402 reads (30%) | called by muse, mutect2, varscan2
- LHCGR | c.732C>T p.S244= | Silent (SNP) | VAF 93/534 reads (17%) | catalogued as rs1297774831, COSV54293226, COSV54302385; called by muse, mutect2, varscan2
- LILRA4 | c.684C>A p.T228= | Silent (SNP) | VAF 28/205 reads (14%) | called by muse, mutect2, varscan2
- LRSAM1 | c.1533C>T p.L511= | Silent (SNP) | VAF 46/486 reads (9%) | called by muse, mutect2
- MC5R | c.843C>G p.L281= | Silent (SNP) | VAF 23/329 reads (7%) | called by muse, mutect2
- MPEG1 | c.984G>A p.K328= | Silent (SNP) | VAF 24/136 reads (18%) | called by muse, mutect2, varscan2
- NAPSA | c.720G>A p.P240= | Silent (SNP) | VAF 32/236 reads (14%) | catalogued as rs377299154; called by muse, mutect2, varscan2
- NKAP | c.258G>T p.A86= | Silent (SNP) | VAF 36/224 reads (16%) | catalogued as rs773545617; called by mutect2, varscan2
- NOL9 | c.1995G>A p.T665= | Silent (SNP) | VAF 25/399 reads (6%) | catalogued as rs146670350; called by muse, mutect2
- NPIPA5 | c.984C>G p.L328= | Silent (SNP) | VAF 70/506 reads (14%) | called by muse, mutect2, varscan2
- NR1H3 | c.675C>T p.N225= | Silent (SNP) | VAF 48/160 reads (30%) | called by muse, mutect2, varscan2
- NUP62 | c.1095G>A p.L365= | Silent (SNP) | VAF 51/245 reads (21%) | called by muse, mutect2, varscan2
- OR4P4 | c.201C>T p.S67= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs760950056, COSV100111568, COSV100111809; called by muse, mutect2, varscan2
- OR6C74 | c.603C>T p.A201= | Silent (SNP) | VAF 104/449 reads (23%) | called by muse, mutect2, varscan2
- PCDHB6 | c.1335C>T p.N445= | Silent (SNP) | VAF 74/773 reads (10%) | catalogued as rs1554277740, COSV50689781; called by muse, mutect2, varscan2
- PHLPP2 | c.1719G>A p.E573= | Silent (SNP) | VAF 45/123 reads (37%) | called by muse, mutect2, varscan2
- PIGN | c.261T>C p.H87= | Silent (SNP) | VAF 65/308 reads (21%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.561G>A p.L187= | Silent (SNP) | VAF 23/502 reads (5%) | catalogued as rs1208694640, COSV99339562; called by muse, mutect2
- RNF103 | c.1449C>T p.D483= | Silent (SNP) | VAF 77/322 reads (24%) | catalogued as rs200645697, COSV99410354; called by muse, mutect2, varscan2
- S100A9 | c.180A>G p.E60= | Silent (SNP) | VAF 37/142 reads (26%) | called by muse, mutect2, varscan2
- SCARA5 | c.684C>A p.R228= | Silent (SNP) | VAF 36/139 reads (26%) | called by muse, mutect2, varscan2
- SDK1 | c.474T>A p.S158= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs905470644; called by muse, mutect2, varscan2
- SLC16A3 | c.909C>T p.F303= | Silent (SNP) | VAF 74/211 reads (35%) | catalogued as rs551415875; called by muse, mutect2, varscan2
- SLC16A3 | c.1188C>T p.L396= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as rs762495427, COSV58364423; called by muse, mutect2, varscan2
- SLC7A10 | c.24G>T p.P8= | Silent (SNP) | VAF 35/141 reads (25%) | called by muse, mutect2, varscan2
- SLC9A2 | c.297T>C p.H99= | Silent (SNP) | VAF 20/60 reads (33%) | called by muse, varscan2
- SNED1 | c.699A>T p.T233= | Silent (SNP) | VAF 45/117 reads (38%) | called by muse, mutect2, varscan2
- SOBP | c.651G>A p.K217= | Silent (SNP) | VAF 48/372 reads (13%) | called by muse, varscan2
- TENM1 | c.7143T>C p.V2381= | Silent (SNP) | VAF 88/464 reads (19%) | called by muse, mutect2, varscan2
- TMEM131L | c.2394G>T p.V798= | Silent (SNP) | VAF 81/244 reads (33%) | catalogued as rs772189224; called by muse, mutect2, varscan2
- TRGV2 | c.219C>A p.S73= | Silent (SNP) | VAF 88/401 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.39432C>T p.C13144= (on ENST00000591111; = p.C5720= on NM_003319.4) | Silent (SNP) | VAF 20/186 reads (11%) | catalogued as rs754335854; called by muse, mutect2, varscan2
- VCL | c.2754C>T p.I918= | Silent (SNP) | VAF 53/426 reads (12%) | called by muse, varscan2
- ZMYM6 | c.1032C>T p.F344= | Silent (SNP) | VAF 24/134 reads (18%) | called by muse, mutect2, varscan2
- ZNF341 | c.972C>T p.C324= (on ENST00000375200 / NM_001282935.1; = p.C317= on NM_032819.4) | Silent (SNP) | VAF 45/230 reads (20%) | called by muse, mutect2, varscan2
- ZNF536 | c.1698C>T p.Y566= | Silent (SNP) | VAF 97/456 reads (21%) | catalogued as rs547191428; called by muse, mutect2, varscan2
- ZNF831 | c.1368C>A p.I456= | Silent (SNP) | VAF 8/111 reads (7%) | catalogued as COSV100926124; called by muse, mutect2
- ZSCAN22 | c.1047G>A p.E349= | Silent (SNP) | VAF 17/188 reads (9%) | called by muse, mutect2
- ACSF3 | c.*289C>T | 3'UTR (SNP) | VAF 56/192 reads (29%) | catalogued as rs1416814631; called by muse, mutect2, varscan2
- ANKRD26P1 | n.989A>T | RNA (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
- ANKRD33 | c.263-76G>T | Intron (SNP) | VAF 64/221 reads (29%) | catalogued as rs1213096937; called by muse, mutect2, varscan2
- ANO1 | c.2198-733A>G | Intron (SNP) | VAF 27/200 reads (14%) | called by muse, mutect2, varscan2
- BANP | c.1345-295del | Intron (DEL) | VAF 55/256 reads (21%) | called by mutect2, pindel, varscan2
- CD58 | c.706+59G>C | Intron (SNP) | VAF 48/139 reads (35%) | called by muse, mutect2, varscan2
- DHCR7 | c.*215G>A | 3'UTR (SNP) | VAF 67/381 reads (18%) | catalogued as rs1320659324; called by muse, mutect2, varscan2
- EIF3L | chr22:37849369 G>A | 5'Flank (SNP) | VAF 19/101 reads (19%) | catalogued as COSV99316501; called by muse, mutect2, varscan2
- FANCD2 | c.65-526G>T | Intron (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- GUCY1B2 | n.962C>T | RNA (SNP) | VAF 75/267 reads (28%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+74543A>T | Intron (SNP) | VAF 26/66 reads (39%) | called by muse, varscan2
- HES2 | chr1:6413241 C>A | 3'Flank (SNP) | VAF 67/232 reads (29%) | called by muse, mutect2, varscan2
- HUWE1 | c.13022+34C>G | Intron (SNP) | VAF 67/261 reads (26%) | called by muse, mutect2, varscan2
- IL17RE | c.1297-28A>T | Intron (SNP) | VAF 59/129 reads (46%) | called by muse, mutect2, varscan2
- KDM2A | c.308-11225G>A | Intron (SNP) | VAF 43/160 reads (27%) | called by muse, mutect2, varscan2
- MEF2C | c.402+154T>A | Intron (SNP) | VAF 71/160 reads (44%) | catalogued as COSV60933979; called by muse, mutect2, varscan2
- NDUFAF5 | c.*459G>A | 3'UTR (SNP) | VAF 14/314 reads (4%) | called by muse, mutect2
- PCMT1 | c.334+841G>A | Intron (SNP) | VAF 22/188 reads (12%) | called by muse, varscan2
- PKD1 | c.2985+9G>T | Intron (SNP) | VAF 21/99 reads (21%) | catalogued as rs1406247347; called by muse, mutect2, varscan2
- PPHLN1 | c.72+7912A>G | Intron (SNP) | VAF 33/186 reads (18%) | catalogued as rs186746804; called by muse, mutect2, varscan2
- PTEN | c.-38C>G | 5'UTR (SNP) | VAF 106/352 reads (30%) | catalogued as COSV100909190; called by muse, varscan2
- RGS11 | c.318+150C>T | Intron (SNP) | VAF 57/207 reads (28%) | called by muse, mutect2, varscan2
- RIC8A | c.85-104C>G | Intron (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- RXRA | n.346C>A | RNA (SNP) | VAF 35/137 reads (26%) | catalogued as rs180839977; called by muse, mutect2, varscan2
- SATL1 | c.-34A>T | 5'UTR (SNP) | VAF 98/289 reads (34%) | called by muse, mutect2, varscan2
- SEPTIN5 | c.55-2282G>T | Intron (SNP) | VAF 67/340 reads (20%) | called by muse, mutect2, varscan2
- SLC22A20P | n.2514G>C | RNA (SNP) | VAF 28/169 reads (17%) | called by muse, mutect2, varscan2
- SLC35B3 | c.-216G>A | 5'UTR (SNP) | VAF 150/648 reads (23%) | called by muse, mutect2, varscan2
- SORCS1 | c.*155G>A | 3'UTR (SNP) | VAF 63/184 reads (34%) | catalogued as COSV53903287; called by muse, mutect2, varscan2
- SPATA31C2 | n.2125C>A | RNA (SNP) | VAF 160/597 reads (27%) | called by muse, mutect2, varscan2
- SPINK2 | c.*48G>A | 3'UTR (SNP) | VAF 81/401 reads (20%) | catalogued as rs534181768; called by muse, mutect2, varscan2
- SYNGAP1 | c.3795-12C>G | Intron (SNP) | VAF 15/184 reads (8%) | called by muse, mutect2
- SYP | c.102+41G>A | Intron (SNP) | VAF 18/332 reads (5%) | catalogued as COSV54296975; called by muse, mutect2
- TACC1 | c.-43G>T | 5'UTR (SNP) | VAF 31/98 reads (32%) | called by muse, mutect2, varscan2
- TMEM135 | c.*7097G>A | 3'UTR (SNP) | VAF 146/352 reads (41%) | called by muse, mutect2, varscan2
- UQCRC1 | c.*12A>T | 3'UTR (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- XIST | n.10548A>T | RNA (SNP) | VAF 53/208 reads (25%) | catalogued as rs1004293372; called by muse, mutect2, varscan2
- ZNF609 | c.747+170G>T | Intron (SNP) | VAF 66/160 reads (41%) | called by muse, mutect2, varscan2
